Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29S, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29S-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

- R elbow melanoma WE. R axilla LN dissection. R elbow melanoma primary.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node,
Axilla

C77.3

MACROSCOPIC DESCRIPTION

(Dr

Two specimens were received.

1. "RIGHT AXILLARY DISSECTION SUTURE - APEX OF AXILLA". The specimen consists of a piece of fatty tissue measuring 150 x 120 x 40mm with an overlying semicircular piece of skin 130 x 32mm and attached muscle measuring 80 x 50 x 20mm. There is a suture at one end of the specimen denoting the apex. The largest lymph node measures 50 x 50 x 25mm and has been sampled for Tumour Banking prior to receipt. This lymph node is situated just deep to the skin surface. Resection margins inked blue.

A-C. Lymph nodes adjacent to apical tie.

A. 1 lymph node.

B. 1 lymph node in two pieces.

C. 2 lymph nodes.

D. 6 lymph nodes.

E. 3 lymph nodes.

F-G. 1 lymph node in three pieces.

H. 3 lymph nodes.

J-K. Profile of largest lymph node which appears to have sampled for Tumour Banking prior to receipt.

L. 1 lymph node in two pieces.

M. 1 lymph node in two pieces.

Lymph nodes dissected from apical tie towards skin surface. No lesions are seen within the attached muscle.

MACROSCOPIC PHOTOGRAPHS TAKEN.

2. "NODULE RIGHT FOREARM HISTO". The specimen consists of an unorientated ellipse of skin 30 x 13 x 3mm, bearing on the skin surface a pale nodule 6 x 4 x 1mm. Resection margins inked blue. Lesion all embedded as one transverse section in block 2A.

MICROSCOPIC REPORT

1. "RIGHT AXILLARY DISSECTION SUTURE - APEX OF AXILLA": The sections show metastatic malignant epithelioid tumour consistent with melanoma (S-100, Melan A and HMB-45 positive) in 4 of the 18 lymph nodes found. 3 of these nodes are totally effaced with very little underlying node identified and extensive extranodal spread. The largest metastases would be the node sampled for tumour banking which was upto 50 x 50 x 25mm macroscopically and is 35 x 15mm in the profile section taken microscopically.

[page 2 of 2]
Requested by

MRN/Na:
Location:
Accession:**HISTOPATHOLOGY REPORT**

2. "NODULE RIGHT FOREARM HISTO": The section of skin show an atypical dermal tumour composed of naevoid and epithelioid cells with deep mitoses. The tumour is consistent with a melanoma. No junctional component or overlying changes of regression are seen, indicative of a metastasis. Clinical correlation is recommended. The melanoma involves one long edge margin and is 1.4mm from the deep margin. There are melanoma cells intimately adjacent to a lymphatic wall but unequivocal lymphovascular or perineural invasion are not seen. There is severe solar elastosis.

SUMMARY

1. Right axillary lymph node dissection - metastatic melanoma in 4 of 18 lymph nodes.
2. Skin of right forearm - consistent with melanoma.

REPORTED BY: Dr :

Source: NCI Genomic Data Commons file 33aedc24-48a4-4c42-bca7-2a5f1db516db (TCGA-EE-A29S.4014EA1A-EB3B-461C-B8C9-AFC32B67DA0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).